Somatic mutation profile of tumor specimen BA2507D (aliquot aq-BA2507D) from BEATAML1.0 case 2377, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.2 years (12,130 days).
Specimen BA2507D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d598f531-13b2-4240-9c09-95efb212466c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2154D (Solid Tissue Normal), aliquot aq-BA2154D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46180b02-89ea-48cb-b2f8-0ded54050fb0

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2, varscan2
- NCOA2 | c.1116G>T p.M372I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs867735917; called by muse, mutect2
- CCDC27 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.087); called by muse, mutect2
- RPAP1 | c.774G>T p.L258F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2
- SLC27A3 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- SPTY2D1 | c.1964G>A p.S655N | Missense Mutation (SNP) | VAF 101/209 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SEMA3A | c.492C>T p.N164= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs148134924; called by muse, mutect2, varscan2
